Somatic mutation profile of tumor specimen TCGA-ER-A3PL-06A (aliquot TCGA-ER-A3PL-06A-11D-A23B-08) from TCGA case TCGA-ER-A3PL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 32.8 years (11,990 days).
Specimen TCGA-ER-A3PL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5110af93-e069-48e2-8b9e-11b972cd339e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A3PL-10A (Blood Derived Normal), aliquot TCGA-ER-A3PL-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b576835-5dad-4868-84da-8ab00146489e

The open-access MAF lists 443 somatic variants for this specimen: 271 protein-altering or splice-affecting, 155 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 242, Silent 155, Nonsense Mutation 18, Intron 9, Splice Region 5, Splice Site 4, 3'UTR 4, 5'UTR 3, RNA 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/156 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IFT122 | c.965C>T p.S322F (on ENST00000348417 / NM_052989.3; = p.S263F on NM_018262.4) | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs267607192, CM103470, COSV56200322; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 17/161 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, mutect2, varscan2
- A2M | c.3911C>T p.S1304L | Missense Mutation (SNP) | VAF 123/244 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV59383638; called by muse, mutect2, varscan2
- A2M | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 114/219 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV59383647; called by muse, mutect2, varscan2
- ABCA13 | c.13709C>T p.S4570F | Missense Mutation (SNP) | VAF 136/247 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68944042; called by muse, mutect2, varscan2
- ABCA7 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs1255012807, COSV54025084; called by muse, mutect2, varscan2
- AC100868.1 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51838929; called by muse, mutect2, varscan2
- ACTN1 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51989046; called by muse, mutect2, varscan2
- ADAL | c.624T>A p.H208Q | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052499; called by muse, mutect2, varscan2
- ADAM23 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV52209231, COSV52223417; called by muse, mutect2, varscan2
- ADAM7 | c.1357-1G>A p.X453_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV51535913; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV54438649; called by muse, mutect2, varscan2
- AHCTF1 | c.5312C>T p.S1771F (on ENST00000366508; = p.S1745F on NM_015446.5) | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV58246617; called by muse, mutect2, varscan2
- ANK3 | c.10948G>A p.D3650N | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.255); catalogued as rs776305737, COSV55047203; called by muse, mutect2, varscan2
- ANXA9 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64484262; called by muse, mutect2, varscan2
- APCDD1 | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100789910; called by muse, mutect2, varscan2
- ARHGEF10 | c.4051C>T p.H1351Y (on ENST00000398564; = p.H1326Y on NM_014629.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50643203; called by muse, mutect2, varscan2
- ARHGEF17 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV55230196; called by muse, mutect2, varscan2
- ATF7IP | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.067); catalogued as COSV53767004; called by muse, mutect2, varscan2
- ATP2C2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV52293331; called by muse, mutect2, varscan2
- ATP8A1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52529991; called by muse, mutect2, varscan2
- AUTS2 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV61386443; called by muse, mutect2, varscan2
- BANK1 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750834847, COSV59839215; called by muse, mutect2, varscan2
- BCOR | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV60701561; called by muse, mutect2, varscan2
- BLM | c.3768T>G p.D1256E | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV61922256; called by muse, mutect2, varscan2
- BNC1 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61756690; called by muse, mutect2, varscan2
- BRCA1 | c.5245C>T p.P1749S | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as CM030005, COSV58785348; called by muse, mutect2, varscan2
- BRIP1 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs565458815, COSV51995020; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- C2orf78 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV68516593; called by muse, mutect2, varscan2
- C4orf17 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV56744569; called by muse, mutect2, varscan2
- C4orf19 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52648970; called by muse, mutect2, varscan2
- CAMTA2 | c.2737C>T p.L913F | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1053449625, COSV52778708, COSV52779880; called by muse, mutect2, varscan2
- CBY2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764935901, COSV60117397; called by muse, mutect2, varscan2
- CCR5 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs764318467, COSV52750993; called by muse, mutect2, varscan2
- CD3D | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778408963, COSV52674127; called by muse, mutect2, varscan2
- CD44 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs190050012, COSV53528388; called by muse, mutect2, varscan2
- CDC42BPB | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.048); catalogued as COSV100775719, COSV63474058; called by muse, mutect2
- CDC45 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54243912; called by muse, mutect2, varscan2
- CDCA4 | c.5T>C p.F2S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60315074; called by muse, mutect2, varscan2
- CDK1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV57349102; called by muse, mutect2, varscan2
- CENPT | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as COSV54648421; called by muse, mutect2, varscan2
- CFAP57 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 62/71 reads (87%) | catalogued as COSV65263800; called by muse, mutect2, varscan2
- CFTR | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50042546; called by muse, mutect2, varscan2
- CHD7 | c.4855G>A p.G1619R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746823883, COSV101418053; called by muse, mutect2, varscan2
- CHD7 | c.4856G>A p.G1619E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101418054; called by muse, mutect2, varscan2
- CHFR | c.658C>T p.P220S (on ENST00000432561 / NM_001161345.1; = p.P179S on NM_018223.2) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57172530; called by muse, mutect2, varscan2
- CHRNA4 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs200644872, COSV64718633; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- CIAO1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV55530403; called by muse, mutect2, varscan2
- CIITA | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV60854647, COSV60859566; called by muse, mutect2
- CNTRL | c.5396G>A p.W1799* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as rs1044778522, COSV53044286; called by muse, mutect2, varscan2
- COL2A1 | c.3233C>T p.P1078L | Missense Mutation (SNP) | VAF 92/101 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV61528435; called by muse, mutect2, varscan2
- CORO2A | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59662222; called by muse, mutect2, varscan2
- CPEB1 | c.830C>T p.S277L (on ENST00000617958; = p.S217L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55617485; called by muse, mutect2, varscan2
- CPNE4 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV70190814; called by muse, mutect2, varscan2
- CPT1C | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV54917971; called by muse, mutect2
- CREBBP | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52115747; called by muse, mutect2, varscan2
- CSF2RA | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs200344796, COSV62623641; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD3 | c.5971G>A p.D1991N (on ENST00000297405 / NM_001363185.1; = p.D1887N on NM_052900.3) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52098344, COSV52135997; called by muse, mutect2, varscan2
- CYP4F2 | c.399G>A p.G133= | Splice Region (SNP) | VAF 57/138 reads (41%) | catalogued as COSV50000402; called by muse, mutect2, varscan2
- CYP4Z1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436665985, COSV61963983; called by muse, mutect2, varscan2
- DCTN1 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as rs746572197, COSV62619758; called by muse, mutect2, varscan2
- DEFB115 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV68722988; called by muse, mutect2, varscan2
- DHCR24 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs149238468, COSV64874770, COSV64875682; called by muse, mutect2, varscan2
- DIO1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 91/150 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs767677380, COSV50776537; called by muse, mutect2, varscan2
- DMBT1 | c.5503G>A p.D1835N (on ENST00000338354 / NM_001377530.1; = p.D1078N on NM_004406.3) | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.901); catalogued as rs750760735, COSV57536608; called by muse, mutect2, varscan2
- DNAH11 | c.12139G>A p.E4047K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60943264; called by muse, mutect2
- DNAH5 | c.4473G>A p.M1491I | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV54208385; called by muse, mutect2, varscan2
- DNAH5 | c.3863G>A p.G1288E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54234064, COSV99444952; called by muse, mutect2
- DNAH5 | c.3862G>A p.G1288R | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54239721; called by muse, mutect2
- DOT1L | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV101288539; called by muse, mutect2, varscan2
- EFCAB6 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs948129216, COSV53059261; called by muse, mutect2, varscan2
- ENPP6 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs575851730, COSV57068617; called by muse, mutect2
- EPB41L1 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1285331476, COSV52434625; called by muse, mutect2, varscan2
- FAAH2 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV66505917; called by muse, mutect2, varscan2
- FAM117A | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.089); catalogued as rs375320243, COSV99539569; called by mutect2, varscan2
- FAM131B | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV68125612; called by muse, mutect2
- FAM53C | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV53510910; called by muse, mutect2, varscan2
- FBN1 | c.4226C>T p.S1409F | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57310921; called by muse, mutect2, varscan2
- FLRT2 | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.587); catalogued as COSV58137309; called by muse, mutect2, varscan2
- FMO2 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 105/444 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52946669; called by muse, mutect2, varscan2
- FNDC7 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs754802918, COSV54751286; called by muse, mutect2, varscan2
- FRMPD1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866932127, COSV63382863; called by muse, mutect2, varscan2
- FSD2 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879262495, COSV58008909; called by muse, mutect2, varscan2
- FUT9 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs371644802; called by muse, mutect2, varscan2
- FZD10 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as COSV57472395, COSV99969484; called by muse, mutect2, varscan2
- GAGE10 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); catalogued as COSV68163718; called by muse, mutect2
- GALNT18 | c.978G>A p.R326= | Splice Region (SNP) | VAF 25/48 reads (52%) | catalogued as COSV99924030; called by muse, mutect2, varscan2
- GALNT18 | c.978-1G>A p.X326_splice | Splice Site (SNP) | VAF 23/46 reads (50%) | catalogued as COSV57151411; called by muse, mutect2, varscan2
- GBP5 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 52/63 reads (83%) | catalogued as rs990506441, COSV58591813; called by muse, mutect2, varscan2
- GIMAP5 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV57529703; called by muse, mutect2, varscan2
- GIMAP6 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 92/422 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV61032660; called by muse, mutect2, varscan2
- GIMAP8 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV56230092, COSV56231287; called by muse, mutect2, varscan2
- GORASP2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52200803; called by muse, mutect2, varscan2
- GPAT3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV52355683; called by muse, mutect2, varscan2
- GPATCH1 | c.1799T>G p.M600R | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99403812; called by muse, mutect2, varscan2
- GPATCH1 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs1216785000, COSV99403816; called by muse, mutect2, varscan2
- GPATCH3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV64651670; called by muse, mutect2, varscan2
- GPR152 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs755398795, COSV56885183; called by muse, mutect2, varscan2
- GPRIN2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV65400556; called by muse, mutect2, varscan2
- GRM5 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100550287, COSV59593851; called by muse, mutect2, varscan2
- GTPBP1 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV53283542; called by muse, mutect2, varscan2
- GZMM | c.545G>A p.W182* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as COSV52741823; called by muse, mutect2
- HCN1 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | catalogued as COSV57496637; called by muse, mutect2, varscan2
- HEPH | c.3374C>T p.A1125V (on ENST00000343002; = p.A858V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57960146; called by muse, mutect2, varscan2
- HOXA1 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58029085; called by muse, mutect2, varscan2
- HTR3A | c.219G>A p.V73= | Splice Region (SNP) | VAF 45/71 reads (63%) | catalogued as COSV55468224; called by muse, mutect2, varscan2
- IL36B | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV52084732; called by muse, mutect2, varscan2
- ILDR1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759748774, COSV56548375; called by muse, mutect2, varscan2
- IMPG1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as rs865789242, COSV64054765; called by muse, mutect2, varscan2
- ING1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1462480935, COSV58167089; called by muse, mutect2, varscan2
- ITSN2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV61944286; called by muse, mutect2, varscan2
- KATNBL1 | c.907T>G p.L303V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56622112; called by muse, mutect2, varscan2
- KCNB1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 64/750 reads (9%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV65566492; called by muse, mutect2
- KCNJ10 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.113); catalogued as rs748553015, COSV63632970; called by muse, mutect2
- KCNK13 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV56411058; called by muse, mutect2, varscan2
- KCTD11 | c.409C>T p.P137S (on ENST00000333751 / NM_001363642.1; = p.P98S on NM_001002914.2) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.242); catalogued as COSV50134227; called by muse, mutect2, varscan2
- KEL | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV62333641; called by muse, mutect2
- KIAA1217 | c.3927G>A p.M1309I | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56813208; called by muse, mutect2, varscan2
- KIF21B | c.3856C>T p.P1286S (on ENST00000422435 / NM_001252100.2; = p.P1273S on NM_017596.4) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV59753314; called by muse, mutect2
- KIF4B | c.3458G>A p.G1153E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.038); catalogued as COSV70527749, COSV70528182; called by muse, mutect2
- KLC3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as rs772906768, COSV67266951; called by muse, mutect2, varscan2
- LCE1B | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.638); catalogued as COSV63980111; called by muse, mutect2, varscan2
- LGALSL | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53230105; called by muse, mutect2, varscan2
- LGI1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65057541; called by muse, mutect2, varscan2
- LMBR1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs781063724, COSV62218540; called by muse, mutect2, varscan2
- LPO | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51857175; called by muse, mutect2, varscan2
- LRP1 | c.6712G>A p.A2238T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV54503690; called by muse, mutect2, varscan2
- LRP1 | c.12436G>A p.E4146K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as rs773620729, COSV54503705; called by muse, mutect2, varscan2
- LRP1B | c.9695G>A p.G3232E | Missense Mutation (SNP) | VAF 91/138 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1338122078, COSV67192995; called by muse, mutect2, varscan2
- LRP6 | c.1709A>T p.D570V | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99742656; called by muse, mutect2, varscan2
- LRP6 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV99742657; called by muse, mutect2, varscan2
- MAGEC2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 101/119 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55998213; called by muse, mutect2, varscan2
- MAP2 | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV52283280, COSV52289414; called by muse, mutect2, varscan2
- MAPKBP1 | c.2012C>T p.P671L (on ENST00000456763 / NM_001128608.2; = p.P665L on NM_014994.3) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52958676, COSV99529228; called by muse, mutect2, varscan2
- MAST1 | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52242158; called by muse, mutect2, varscan2
- MCHR2 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56000362; called by muse, mutect2, varscan2
- MEI1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.461); catalogued as rs989797393, COSV100299705; called by muse, mutect2, varscan2
- MLLT10 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.987); catalogued as COSV56992283; called by muse, mutect2
- MRC2 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as rs940278977, COSV57637363; called by muse, mutect2
- MROH9 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63010231; called by muse, mutect2, varscan2
- MRTFB | c.2441C>T p.P814L (on ENST00000571589 / NM_001365412.2; = p.P764L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV57956460; called by muse, mutect2, varscan2
- MUC16 | c.29551G>A p.D9851N | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.467); catalogued as COSV67450022; called by muse, mutect2
- MUC16 | c.29255C>T p.S9752F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.412); catalogued as COSV67450031; called by muse, mutect2, varscan2
- MUC16 | c.24008C>T p.S8003L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as COSV67450042; called by muse, varscan2
- MUC16 | c.22040C>T p.T7347I | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.319); catalogued as rs778922445, COSV67450059; called by muse, mutect2, varscan2
- MUC17 | c.3263G>A p.G1088D | Missense Mutation (SNP) | VAF 141/1018 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as rs772223293, COSV60281813; called by muse, mutect2, varscan2
- MUC3A | c.7997G>A p.G2666E | Missense Mutation (SNP) | VAF 122/912 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.537); catalogued as rs762464654, COSV60211557; called by muse, mutect2, varscan2
- MYBPC3 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1565625856, COSV57023980, COSV57032286; called by muse, mutect2, varscan2
- MYH2 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 119/291 reads (41%) | catalogued as COSV55432888; called by muse, mutect2, varscan2
- MYH4 | c.5398C>T p.R1800C | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770067160, COSV55111784; called by muse, mutect2, varscan2
- MYO15A | c.10370C>T p.P3457L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs945678260, COSV52752896; called by muse, mutect2, varscan2
- MYO18B | c.2852A>G p.N951S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.336); catalogued as rs989529670, COSV59127342; called by muse, mutect2, varscan2
- MYO18B | c.6709C>T p.P2237S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV59127353; called by muse, mutect2, varscan2
- MYO7A | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs1555072386, COSV68683438; called by muse, mutect2, varscan2
- MYOCD | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58498486; called by muse, varscan2
- NCKAP5 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV58430864; called by muse, mutect2, varscan2
- NFASC | c.3655G>A p.E1219K (on ENST00000339876 / NM_001378329.1; = p.E1148K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV58377277; called by muse, mutect2, varscan2
- NID2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV53493702, COSV53500989; called by muse, mutect2, varscan2
- NLRP7 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100052801, COSV60171722; called by muse, mutect2, varscan2
- NOS1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 240/299 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042913420, COSV57606613; called by muse, mutect2, varscan2
- NPNT | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs770084338, COSV59752271; called by muse, mutect2, varscan2
- NRXN1 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV58439301; called by muse, mutect2, varscan2
- NUF2 | c.467A>T p.N156I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV99616210; called by muse, mutect2, varscan2
- NUP155 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV51527544; called by muse, mutect2
- OGDHL | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867750245, COSV65101316; called by muse, mutect2, varscan2
- OGDHL | c.2057C>G p.T686R | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV65101321; called by muse, mutect2, varscan2
- OPRL1 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61091059; called by muse, mutect2
- OR1I1 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV52917435; called by muse, mutect2, varscan2
- OR2F1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs1160958690, COSV67330832; called by muse, mutect2, varscan2
- OR4A15 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.726); catalogued as rs1197084313, COSV59033863; called by muse, mutect2, varscan2
- OR4A15 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 133/224 reads (59%) | catalogued as COSV59033869; called by muse, mutect2, varscan2
- OR4A5 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV60521730, COSV60523084; called by muse, mutect2, varscan2
- OR4A5 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as rs531447165, COSV60521722; called by muse, mutect2, varscan2
- OR56A3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 101/209 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs775882746, COSV61568604; called by muse, mutect2, varscan2
- OR5V1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65826649; called by muse, mutect2, varscan2
- OR6B2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV53152938; called by muse, mutect2
- OR6C6 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64455527; called by muse, mutect2, varscan2
- OR7D4 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58071230; called by muse, mutect2, varscan2
- PAPPA | c.4404C>A p.F1468L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV60278534; called by muse, mutect2, varscan2
- PCDH18 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100787569, COSV61266764; called by muse, mutect2, varscan2
- PCDHA13 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.503); catalogued as rs199942713, COSV56482025; called by muse, mutect2, varscan2
- PCDHB1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60629739; called by muse, mutect2
- PCDHB14 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV53386625; called by muse, mutect2, varscan2
- PCDHB3 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs1563837333, COSV50564880; called by muse, mutect2, varscan2
- PCDHGB5 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 32/205 reads (16%) | catalogued as COSV53909297; called by muse, mutect2, varscan2
- PCLO | c.10446G>A p.W3482* | Nonsense Mutation (SNP) | VAF 51/104 reads (49%) | catalogued as COSV61619716; called by muse, mutect2, varscan2
- PCNX2 | c.3066G>A p.K1022= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as COSV50784486; called by muse, mutect2, varscan2
- PHRF1 | c.385T>G p.Y129D | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52752059; called by muse, mutect2, varscan2
- PIBF1 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as COSV58320788; called by muse, mutect2, varscan2
- PLCE1 | c.5179G>T p.G1727C | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV53339882; called by muse, mutect2, varscan2
- PLCE1 | c.5719C>T p.R1907C | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974611612, COSV99593911; called by muse, varscan2
- POTEH | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 158/573 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.395); catalogued as rs746449731, COSV58880731; called by muse, varscan2
- PPP1R13B | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52449350; called by muse, mutect2, varscan2
- PRAG1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750533526, COSV58158090; called by muse, mutect2, varscan2
- PRAG1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.17); catalogued as rs751572450, COSV58158107; called by muse, mutect2, varscan2
- PRB2 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 115/802 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); catalogued as rs776009756, COSV66982382; called by muse, varscan2
- PREX2 | c.3414G>A p.M1138I | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV55755152, COSV55778459; called by muse, mutect2, varscan2
- PRKCH | c.1576C>T p.L526F | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60646212; called by muse, mutect2, varscan2
- PRUNE2 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65038489; called by muse, mutect2, varscan2
- PTK7 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV57846743; called by muse, mutect2
- QRICH1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV62614648; called by muse, mutect2, varscan2
- RALGAPB | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53435229; called by muse, mutect2
- RGPD2 | c.5212G>A p.G1738R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100552883; called by mutect2, varscan2
- ROBO4 | c.1695G>A p.W565* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as COSV60621904; called by muse, mutect2, varscan2
- RP1L1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs750614061, COSV61443975; called by muse, mutect2, varscan2
- RPS6KA5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs1315968352, COSV56219661; called by muse, mutect2, varscan2
- RTL4 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 115/193 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as COSV61205710; called by muse, mutect2, varscan2
- RYR1 | c.11362G>A p.E3788K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV62090965, COSV62091055; called by muse, mutect2, varscan2
- SALL1 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs554506639, COSV51754195; called by muse, mutect2, varscan2
- SAMD9L | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV59080833; called by muse, mutect2, varscan2
- SCAF1 | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV59190734; called by muse, mutect2, varscan2
- SCAP | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99652517, COSV99653502; called by muse, mutect2
- SEC14L4 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.195); catalogued as rs769201861, COSV55398672; called by muse, mutect2, varscan2
- SEMA6A | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56709621; called by muse, mutect2, varscan2
- SETMAR | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.019); catalogued as rs145940333; called by muse, mutect2, varscan2
- SHANK1 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV53244771; called by muse, mutect2, varscan2
- SHROOM4 | c.3997C>T p.R1333* | Nonsense Mutation (SNP) | VAF 11/13 reads (85%) | catalogued as rs1557247080, COSV56785509; called by muse, mutect2, varscan2
- SIGLEC12 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs1426292237, COSV52459882; called by muse, mutect2
- SIRPB1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53537733; called by muse, mutect2, varscan2
- SLC22A23 | c.1581G>A p.G527= | Splice Region (SNP) | VAF 9/47 reads (19%) | catalogued as COSV66676804; called by muse, mutect2, varscan2
- SLC35G3 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV52010437; called by muse, mutect2, varscan2
- SLC36A2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV58862312; called by muse, mutect2, varscan2
- SLC4A1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.083); catalogued as COSV52258738; called by muse, mutect2, varscan2
- SMARCA2 | c.4108C>T p.R1370C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100190736, COSV56645431; called by muse, mutect2, varscan2
- SORBS1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV53354034; called by muse, mutect2, varscan2
- SORCS3 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs866829069, COSV63803824; called by muse, mutect2, varscan2
- STAB2 | c.5734C>T p.P1912S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66335379; called by muse, mutect2, varscan2
- STAG3 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV57928046; called by muse, mutect2, varscan2
- SUSD2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as rs548470214, COSV64202996; called by muse, mutect2, varscan2
- SYT6 | c.799C>T p.P267S (on ENST00000610222 / NM_001366225.1; = p.P182S on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65772706; called by muse, mutect2, varscan2
- TBATA | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV54717492; called by muse, mutect2, varscan2
- TBXAS1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV54941646; called by muse, mutect2
- TC2N | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs766880081, COSV61746165, COSV61747755; called by muse, mutect2, varscan2
- TEKT1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58622350; called by muse, mutect2, varscan2
- TEPP | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as rs774740704, COSV52042679, COSV52043390; called by muse, mutect2, varscan2
- TG | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); catalogued as rs1021463864, COSV55067158; called by muse, mutect2, varscan2
- TLR4 | c.673G>A p.E225K (on ENST00000355622 / NM_138554.5; = p.E185K on NM_003266.4) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62922585, COSV62922718; called by muse, mutect2, varscan2
- TLR4 | c.1817G>A p.R606Q (on ENST00000355622 / NM_138554.5; = p.R566Q on NM_003266.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs773808914, COSV62922463; called by muse, mutect2, varscan2
- TMEM43 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100044505, COSV60145452; called by muse, mutect2, varscan2
- TPTE2 | c.1003C>T p.L335F (on ENST00000400230 / NM_199254.2; = p.L258F on NM_130785.3) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV55017075; called by muse, mutect2
- TRIM6-TRIM34 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61454498, COSV61459360; called by muse, mutect2, varscan2
- TRPM4 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99419221; called by muse, mutect2, varscan2
- TSC2 | c.5161A>C p.M1721L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.874); catalogued as rs45517407, CD983906, COSV51911806, COSV51920503; ClinVar: not provided; called by muse, mutect2
- TTLL4 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.073); catalogued as COSV51435219; called by muse, mutect2, varscan2
- TTN | c.92074C>T p.R30692C (on ENST00000591111; = p.R23268C on NM_003319.4) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | PolyPhen probably damaging (0.973); catalogued as rs368918455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBL7 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV63705754; called by muse, mutect2, varscan2
- UMODL1 | c.2837C>T p.P946L (on ENST00000408910 / NM_001004416.2; = p.P1074L on NM_173568.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs1459941239, COSV68569324; called by muse, mutect2, varscan2
- UPB1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV58112356; called by muse, varscan2
- USH2A | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 107/171 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1395592455, COSV56335490; called by muse, mutect2, varscan2
- USP6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); catalogued as COSV51476554; called by muse, mutect2
- USP6 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV51476578; called by muse, mutect2, varscan2
- VPS13D | c.5173C>T p.L1725F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50624497; called by muse, mutect2, varscan2
- VRK1 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53708166; called by muse, mutect2, varscan2
- WDR91 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60368786; called by muse, mutect2, varscan2
- WDR91 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747135607, COSV60368797; called by muse, mutect2, varscan2
- WSCD2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54578902; called by muse, mutect2, varscan2
- ZBTB4 | c.3002G>A p.R1001K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV60139226; called by muse, mutect2, varscan2
- ZDHHC2 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1228079494, COSV50497367; called by muse, mutect2, varscan2
- ZDHHC8 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1305261805, COSV57709203; called by muse, mutect2, varscan2
- ZNF284 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69690726; called by muse, mutect2, varscan2
- ZNF526 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs368283243, COSV55898589; called by muse, mutect2, varscan2
- ZNF570 | c.1193A>C p.N398T | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.445); catalogued as COSV57578252; called by muse, mutect2, varscan2
- ZNF624 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs373841132, COSV60939703; called by muse, mutect2, varscan2
- ZNF804A | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV56438172, COSV56450498; called by muse, mutect2, varscan2
- ZNF836 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs376958843; called by muse, mutect2, varscan2
- ZP3 | c.536-1G>A p.X179_splice (on ENST00000394857 / NM_001110354.2; = p.X128_splice on NM_007155.6) | Splice Site (SNP) | VAF 23/142 reads (16%) | catalogued as COSV60630911; called by muse, mutect2, varscan2
- GAGE2E | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 44/1018 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPIN3 | c.165_174del p.H56Kfs*7 | Frame Shift Del (DEL) | VAF 36/185 reads (19%) | called by mutect2, pindel, varscan2
- VCL | c.2514_2519del p.Q838_P840delinsH | In Frame Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- ZNF367 | c.692-17_692-1del p.X231_splice | Splice Site (DEL) | VAF 43/90 reads (48%) | called by mutect2, pindel, varscan2
- ABCA2 | c.5403C>T p.T1801= (on ENST00000614293; = p.T1771= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV55798260; called by muse, mutect2, varscan2
- ABCA9 | c.3786G>A p.Q1262= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV60621474; called by muse, mutect2, varscan2
- ABHD16A | c.747T>C p.N249= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV65451454; called by muse, mutect2, varscan2
- ACAD10 | c.36C>T p.L12= | Silent (SNP) | VAF 81/95 reads (85%) | catalogued as COSV58154546; called by muse, mutect2, varscan2
- ACSBG2 | c.1228C>T p.L410= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV53123243, COSV53127362; called by muse, mutect2, varscan2
- ADA2 | c.426G>A p.G142= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs143138564, COSV52830574; called by muse, mutect2, varscan2
- ADAMTS13 | c.2922C>T p.I974= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV63020195; called by muse, varscan2
- AKAP12 | c.2649G>A p.E883= | Silent (SNP) | VAF 61/95 reads (64%) | catalogued as rs978629614, COSV53570871; called by muse, mutect2, varscan2
- AKAP6 | c.5850G>A p.K1950= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV55206606, COSV99799461; called by muse, mutect2, varscan2
- ANO2 | c.342C>T p.F114= (on ENST00000356134 / NM_001278597.3; = p.F118= on NM_001278596.3) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs868713652, COSV59008935; called by muse, mutect2, varscan2
- ARHGEF18 | c.855C>T p.I285= (on ENST00000359920 / NM_001130955.2; = p.I181= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV60467649; called by muse, mutect2, varscan2
- ARHGEF18 | c.3201C>T p.P1067= (on ENST00000359920 / NM_001130955.2; = p.P963= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs775197129, COSV60467669; called by muse, mutect2, varscan2
- ARSA | c.1332G>T p.L444= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs540031338, COSV53349995; called by muse, mutect2, varscan2
- AXL | c.2547G>A p.K849= (on ENST00000301178 / NM_021913.5; = p.K840= on NM_001699.6) | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV56564622; called by muse, mutect2
- BRAF | c.1920G>A p.V640= (on ENST00000288602 / NM_001374244.1; = p.V600= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 99/157 reads (63%) | catalogued as COSV56107175, COSV56109586; called by muse, mutect2, varscan2
- C1orf226 | c.156G>A p.K52= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV63394595; called by muse, mutect2, varscan2
- CACNA1B | c.3786C>T p.I1262= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs771339845, COSV53116411; called by muse, mutect2, varscan2
- CACNA1C | c.2700G>A p.T900= | Silent (SNP) | VAF 71/129 reads (55%) | catalogued as rs200717140, COSV59698322; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D4 | c.1830G>A p.R610= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV54945884; called by muse, mutect2
- CAMTA2 | c.2736C>T p.A912= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV99236257; called by mutect2, varscan2
- CCDC141 | c.3987G>A p.E1329= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV55369948; called by muse, mutect2, varscan2
- CCDC191 | c.75G>A p.R25= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as COSV55559010; called by muse, mutect2, varscan2
- CCM2 | c.1113C>T p.T371= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV51846877; called by muse, mutect2, varscan2
- CCT8L2 | c.1560C>T p.I520= | Silent (SNP) | VAF 35/210 reads (17%) | catalogued as rs529271182, COSV63461718; called by muse, mutect2, varscan2
- CFAP45 | c.1089G>A p.R363= | Silent (SNP) | VAF 48/363 reads (13%) | catalogued as COSV63648251; called by muse, mutect2, varscan2
- CHRNB3 | c.402C>T p.I134= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs768194990, COSV51493627; called by muse, mutect2, varscan2
- CLCN7 | c.1125C>T p.I375= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1410701535, COSV51969073; called by muse, mutect2, varscan2
- CLPTM1 | c.204C>T p.A68= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV61611300; called by muse, mutect2, varscan2
- CLUH | c.444C>T p.F148= (on ENST00000435359; = p.F186= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV70928003; called by muse, mutect2, varscan2
- CNTNAP2 | c.1632C>T p.F544= | Silent (SNP) | VAF 28/354 reads (8%) | catalogued as rs778731812, COSV62144222; ClinVar: likely benign; called by muse, mutect2
- COL1A2 | c.2625C>T p.L875= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV51952733; called by muse, mutect2
- COL6A3 | c.9142C>T p.L3048= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV55081746; called by muse, mutect2, varscan2
- COL6A5 | c.7071G>A p.L2357= (on ENST00000312481; = p.L2353= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV55194836; called by muse, mutect2, varscan2
- COQ2 | c.627C>T p.S209= | Silent (SNP) | VAF 48/163 reads (29%) | catalogued as COSV61021167; called by muse, mutect2, varscan2
- CORO7 | c.2283C>T p.L761= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52028487; called by muse, mutect2, varscan2
- CPNE7 | c.1398C>T p.I466= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV52011347; called by muse, mutect2, varscan2
- CREB5 | c.1125C>T p.D375= (on ENST00000357727 / NM_182898.4; = p.D368= on NM_004904.3) | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs751547946, COSV63217943; called by muse, mutect2, varscan2
- CSMD1 | c.6285G>A p.Q2095= (on ENST00000520002; = p.Q2094= on NM_033225.6) | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV59289956; called by muse, mutect2, varscan2
- CYSLTR1 | c.645C>T p.T215= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as COSV64819514, COSV64820063; called by muse, mutect2, varscan2
- DIDO1 | c.1665C>T p.S555= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs142748214; called by muse, mutect2, varscan2
- DISP1 | c.2091C>T p.A697= | Silent (SNP) | VAF 21/226 reads (9%) | catalogued as COSV52655597; called by muse, mutect2
- DLL4 | c.1137G>A p.E379= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV51061173; called by muse, mutect2, varscan2
- DNAH9 | c.5865C>T p.F1955= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs139063832; called by muse, mutect2, varscan2
- DNM1 | c.1773G>A p.T591= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs762812488, COSV57849538; called by muse, mutect2, varscan2
- DYRK3 | c.729G>A p.E243= | Silent (SNP) | VAF 17/192 reads (9%) | catalogued as COSV65605490; called by muse, mutect2
- EEFSEC | c.1566C>T p.F522= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs776866885, COSV54620932; called by muse, mutect2, varscan2
- ELSPBP1 | c.399C>T p.S133= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV60413058; called by muse, mutect2, varscan2
- ERICH3 | c.630G>A p.R210= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV58598724, COSV58601028; called by muse, mutect2, varscan2
- EXD1 | c.825G>A p.V275= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV59253008; called by muse, mutect2, varscan2
- EXT2 | c.90C>T p.F30= (on ENST00000343631; = p.F63= on NM_000401.3) | Silent (SNP) | VAF 95/179 reads (53%) | catalogued as COSV59147469; called by muse, mutect2, varscan2
- FAM117A | c.1257G>A p.R419= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53603655; called by mutect2, varscan2
- FAM91A1 | c.609C>T p.L203= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1271719205, COSV58235973; called by muse, mutect2, varscan2
- FAM91A1 | c.1986C>T p.S662= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as COSV58235979; called by muse, mutect2, varscan2
- FLNC | c.5145C>T p.V1715= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as COSV57951699; called by muse, mutect2, varscan2
- FNDC1 | c.5385C>T p.F1795= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs571734975, COSV51932133; called by muse, mutect2, varscan2
- FOXN1 | c.75G>A p.G25= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56880744; called by muse, mutect2
- GAB3 | c.276C>T p.S92= | Silent (SNP) | VAF 128/151 reads (85%) | catalogued as COSV65818909; called by muse, mutect2, varscan2
- GJC3 | c.804G>A p.Q268= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV57209945; called by muse, mutect2, varscan2
- GLS2 | c.969C>T p.A323= | Silent (SNP) | VAF 154/188 reads (82%) | catalogued as rs866868685, COSV57665244; called by muse, mutect2, varscan2
- GOLGA2 | c.2553G>A p.E851= | Silent (SNP) | VAF 121/180 reads (67%) | catalogued as COSV57849550; called by muse, mutect2, varscan2
- GRB10 | c.1132T>C p.L378= (on ENST00000398812; = p.L332= on NM_001001549.3) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV60007921; called by muse, mutect2, varscan2
- GTPBP6 | c.885C>T p.P295= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs367777349, COSV58204547; called by muse, mutect2, varscan2
- H1-5 | c.267C>T p.S89= | Silent (SNP) | VAF 256/348 reads (74%) | catalogued as rs372908864; called by muse, mutect2, varscan2
- HIF3A | c.60G>A p.R20= (on ENST00000377670 / NM_152795.4; = p.R18= on NM_152794.4) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52196182; called by muse, mutect2
- HK3 | c.2157G>A p.G719= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as rs764366252, COSV52837566; called by muse, mutect2, varscan2
- HLA-DPA1 | c.537C>T p.F179= | Silent (SNP) | VAF 48/398 reads (12%) | catalogued as COSV101343121, COSV70088358; called by muse, mutect2
- HTR1A | c.1023G>A p.R341= | Silent (SNP) | VAF 78/168 reads (46%) | catalogued as rs1386635764, COSV60500035; called by muse, mutect2, varscan2
- IGHE | c.1044G>A p.Q348= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- IGSF10 | c.2223G>A p.R741= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1404911716, COSV56782319, COSV99178760; called by muse, mutect2, varscan2
- IL12RB1 | c.1014C>T p.T338= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV59096168; called by muse, mutect2, varscan2
- ITIH2 | c.933C>T p.I311= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1253146163, COSV64432203; called by muse, mutect2, varscan2
- ITPR3 | c.5730C>T p.F1910= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs953357095, COSV65406416; called by muse, mutect2, varscan2
- JPH3 | c.831G>A p.E277= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV52464942; called by muse, mutect2, varscan2
- KANK2 | c.1503C>T p.F501= (on ENST00000586659 / NM_001379562.1; = p.F509= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1268625980, COSV62006763; called by muse, mutect2, varscan2
- KIAA0825 | c.291C>T p.F97= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56948681; called by muse, mutect2, varscan2
- KIAA1755 | c.255G>A p.R85= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as rs768266905, COSV54074337; called by muse, mutect2, varscan2
- KIF13B | c.2475G>A p.Q825= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV72879449; called by muse, mutect2, varscan2
- KIF25 | c.528C>T p.L176= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs556267996, COSV63026480; called by muse, mutect2, varscan2
- KRT1 | c.1452C>T p.T484= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52865326; called by muse, varscan2
- LRRK1 | c.514C>T p.L172= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV52603687; called by muse, mutect2, varscan2
- LYST | c.10557G>A p.K3519= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV67704039; called by muse, mutect2
- MAGI3 | c.2676C>T p.D892= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as rs1406073927, COSV56829538; called by muse, mutect2
- MED12 | c.5931C>T p.H1977= | Silent (SNP) | VAF 60/66 reads (91%) | catalogued as COSV61333843; called by muse, mutect2, varscan2
- MEI1 | c.1572C>T p.A524= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100299709; called by muse, mutect2, varscan2
- MICALL2 | c.2673C>T p.S891= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs150270558, COSV99875991; called by muse, mutect2, varscan2
- MSR1 | c.1263G>A p.G421= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs979975129, COSV50507472; called by muse, mutect2, varscan2
- MTF1 | c.567C>T p.I189= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV65988500; called by muse, mutect2, varscan2
- MTNR1A | c.204C>T p.S68= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV56155228; called by muse, mutect2, varscan2
- MUC16 | c.35709C>T p.S11903= | Silent (SNP) | VAF 92/185 reads (50%) | catalogued as COSV67450005; called by muse, mutect2, varscan2
- MUC17 | c.36G>A p.L12= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV59331112; called by muse, mutect2, varscan2
- MYH4 | c.3252C>T p.L1084= | Silent (SNP) | VAF 82/176 reads (47%) | catalogued as COSV55113581; called by muse, mutect2, varscan2
- NBEA | c.4722G>A p.L1574= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as rs1198537404, COSV59764486; called by muse, mutect2, varscan2
- NLRP5 | c.1761C>T p.L587= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV66762578; called by mutect2, varscan2
- NUF2 | c.468C>T p.N156= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs144568103; called by muse, mutect2, varscan2
- OR13F1 | c.327C>T p.S109= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV58250907; called by muse, mutect2, varscan2
- OR1N1 | c.861C>T p.I287= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as COSV59195059; called by muse, mutect2, varscan2
- OR2D2 | c.643C>T p.L215= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV55056537; called by muse, mutect2, varscan2
- OR4M1 | c.66G>A p.E22= | Silent (SNP) | VAF 66/178 reads (37%) | catalogued as COSV60059854; called by muse, mutect2, varscan2
- OR4N2 | c.732C>T p.I244= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as COSV60050267; called by muse, mutect2, varscan2
- OR51L1 | c.936G>A p.R312= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV58624077; called by muse, mutect2, varscan2
- OR51T1 | c.759C>T p.F253= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV59024039; called by muse, mutect2, varscan2
- PCDHA5 | c.1386C>T p.F462= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV65349989; called by muse, mutect2, varscan2
- PCDHA6 | c.786C>T p.I262= | Silent (SNP) | VAF 78/174 reads (45%) | catalogued as rs782226224, COSV65350000; called by muse, mutect2, varscan2
- PCDHAC1 | c.1224C>T p.I408= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV53839221, COSV99164991; called by muse, mutect2
- PCLO | c.9327C>T p.S3109= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV61619732; called by muse, mutect2, varscan2
- PCYT1A | c.1056C>T p.S352= | Silent (SNP) | VAF 21/204 reads (10%) | catalogued as rs142070722; called by muse, mutect2
- PEG3 | c.2484G>A p.R828= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as COSV55627061; called by muse, mutect2, varscan2
- PLAGL2 | c.1245C>T p.S415= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1384520663, COSV55787600; called by muse, mutect2
- PLCB3 | c.273C>T p.G91= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV54186225; called by muse, mutect2, varscan2
- PLCE1 | c.3876G>A p.S1292= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as rs886047501, COSV53339856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCE1 | c.5718C>T p.F1906= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as COSV99593905; called by muse, varscan2
- PLD1 | c.2352C>T p.F784= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as COSV60565932; called by muse, mutect2, varscan2
- POU4F3 | c.660G>A p.V220= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV57942615; called by muse, mutect2, varscan2
- PPM1H | c.900C>T p.I300= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57371140; called by muse, mutect2
- PRR14 | c.375C>T p.S125= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV54910904; called by muse, mutect2, varscan2
- PRR19 | c.81G>A p.R27= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs1277609655, COSV56624016; called by muse, mutect2, varscan2
- PTCH1 | c.2847C>T p.V949= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV59465051; called by muse, mutect2, varscan2
- RADIL | c.3132C>T p.D1044= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV101271294; called by muse, mutect2
- RECQL5 | c.693C>T p.F231= | Silent (SNP) | VAF 144/487 reads (30%) | catalogued as rs1414123075, COSV53126934; called by muse, mutect2, varscan2
- RHAG | c.969G>A p.R323= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as rs956230967, COSV100006410; called by muse, mutect2
- RP1L1 | c.2145C>T p.A715= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs373894974, COSV66752505; called by muse, mutect2, varscan2
- RTEL1 | c.2145C>T p.F715= | Silent (SNP) | VAF 20/205 reads (10%) | catalogued as rs762607146, COSV58891110; ClinVar: likely benign; called by muse, mutect2
- RYR2 | c.13714T>C p.L4572= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV63667481; called by muse, mutect2, varscan2
- SAMD9L | c.2460C>T p.S820= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as rs757031410, COSV59080509; called by muse, mutect2, varscan2
- SCN2A | c.2745C>T p.S915= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as COSV51834234; called by muse, mutect2, varscan2
- SHANK1 | c.1893C>T p.F631= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV53244752; called by muse, mutect2, varscan2
- SLC44A5 | c.2094C>T p.F698= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs746770659, COSV63769219; called by muse, mutect2, varscan2
- SLCO4C1 | c.1165C>T p.L389= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV60513279; called by muse, mutect2, varscan2
- SLCO6A1 | c.276C>T p.G92= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs764577906, COSV101134898, COSV65806331; called by muse, mutect2, varscan2
- SULT1C3 | c.585C>T p.H195= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV61252511; called by muse, mutect2
- SV2B | c.1608C>T p.F536= | Silent (SNP) | VAF 95/179 reads (53%) | catalogued as COSV57698755; called by muse, mutect2, varscan2
- SVEP1 | c.9693C>T p.F3231= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV52836439, COSV99928434; called by muse, mutect2, varscan2
- SYT13 | c.996C>T p.T332= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV50072693; called by muse, mutect2, varscan2
- TIMELESS | c.180C>T p.I60= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV57509532; called by muse, varscan2
- TM9SF2 | c.759C>T p.P253= | Silent (SNP) | VAF 95/207 reads (46%) | catalogued as rs748080958, COSV64506310; called by muse, mutect2, varscan2
- TMEM89 | c.366C>T p.L122= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs868602873, COSV56570281; called by muse, mutect2, varscan2
- TRAK1 | c.1509C>T p.S503= (on ENST00000327628 / NM_001349247.2; = p.S445= on NM_014965.5) | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as COSV58256347; called by muse, mutect2, varscan2
- TRIM24 | c.2871C>T p.S957= (on ENST00000343526 / NM_015905.3; = p.S923= on NM_003852.4) | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV58969752; called by muse, mutect2, varscan2
- TRPM4 | c.2829C>T p.A943= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99419225; called by muse, mutect2, varscan2
- TTC21A | c.1185G>A p.K395= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs775333030, COSV57183445; called by muse, mutect2, varscan2
- TTLL8 | c.243C>T p.F81= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99838095; called by muse, mutect2
- UBXN1 | c.462G>A p.K154= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV53656411, COSV53657133; called by muse, mutect2, varscan2
- ULK1 | c.2007C>T p.P669= | Silent (SNP) | VAF 47/59 reads (80%) | catalogued as rs200684485, COSV58855027; called by muse, mutect2, varscan2
- UTS2R | c.255C>T p.S85= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1256455495, COSV57452445; called by muse, mutect2, varscan2
- VCAN | c.4683C>T p.A1561= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV54098630, COSV54105209; called by muse, mutect2, varscan2
- VRTN | c.216G>A p.R72= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV56439448; called by muse, mutect2, varscan2
- WDR62 | c.2238G>A p.P746= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs190314006, COSV54332340, COSV54336044; called by muse, mutect2, varscan2
- WDSUB1 | c.237C>A p.V79= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV63067056; called by muse, mutect2, varscan2
- XIRP2 | c.9450C>T p.F3150= (on ENST00000628543; = p.F3325= on NM_152381.6) | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs1553505593, COSV54686043, COSV54714181; called by muse, mutect2, varscan2
- XKR5 | c.117C>T p.A39= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV68398002; called by muse, mutect2, varscan2
- XXYLT1 | c.1032C>T p.L344= | Silent (SNP) | VAF 49/63 reads (78%) | catalogued as COSV59981692; called by muse, mutect2, varscan2
- ZDHHC14 | c.834C>T p.S278= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV58193268, COSV58195993; called by muse, mutect2
- ZNF529 | c.1179C>T p.P393= | Silent (SNP) | VAF 27/204 reads (13%) | catalogued as COSV61899517; called by muse, mutect2, varscan2
- ZNF646 | c.5055C>T p.S1685= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV54922946; called by muse, mutect2, varscan2
- ZSCAN18 | c.738C>T p.L246= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs142570646; called by mutect2, varscan2
- ADK | c.*70C>T | 3'UTR (SNP) | VAF 54/112 reads (48%) | catalogued as COSV54199982; called by muse, mutect2, varscan2
- CEACAM8 | c.-1C>T | 5'UTR (SNP) | VAF 64/187 reads (34%) | catalogued as COSV99747465; called by muse, mutect2, varscan2
- COL5A1 | c.654+7281C>T | Intron (SNP) | VAF 34/47 reads (72%) | catalogued as COSV100879625; called by muse, mutect2, varscan2
- CXCL12 | c.266+2628G>A | Intron (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100638883; called by muse, mutect2, varscan2
- DUSP13 | c.*475G>A | 3'UTR (SNP) | VAF 12/64 reads (19%) | catalogued as COSV57813253; called by muse, mutect2, varscan2
- FAM183BP | n.1185G>A | RNA (SNP) | VAF 91/242 reads (38%) | called by muse, mutect2, varscan2
- LIMK2 | c.1773-1376C>T | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99313940; called by muse, mutect2, varscan2
- MAGI1 | c.2417-3580G>A | Intron (SNP) | VAF 21/82 reads (26%) | catalogued as rs868607850, COSV100439709; called by muse, mutect2, varscan2
- NACA | c.71-2837C>T | Intron (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100771125, COSV100771692; called by muse, mutect2, varscan2
- OBSCN | c.11659+4941G>A | Intron (SNP) | VAF 14/130 reads (11%) | catalogued as COSV99474600; called by mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15066G>A | Intron (SNP) | VAF 67/165 reads (41%) | catalogued as rs746565332, COSV101043144, COSV67450687; called by muse, mutect2, varscan2
- TGIF1 | c.-367C>T | 5'UTR (SNP) | VAF 49/94 reads (52%) | catalogued as COSV57906726; called by muse, mutect2, varscan2
- TMC5 | c.1049-3435C>T | Intron (SNP) | VAF 27/82 reads (33%) | catalogued as COSV54904463; called by muse, mutect2, varscan2
- UPF2 | c.*232C>T | 3'UTR (SNP) | VAF 28/44 reads (64%) | catalogued as rs368473400; called by muse, mutect2, varscan2
- UROC1 | c.903-565G>A | Intron (SNP) | VAF 15/88 reads (17%) | catalogued as COSV52030420; called by muse, mutect2, varscan2
- ZNF490 | c.-1G>A | 5'UTR (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100267231; called by muse, mutect2, varscan2
- ZNF99 | c.*1016G>A | 3'UTR (SNP) | VAF 46/106 reads (43%) | catalogued as rs762738760, COSV68056776; called by muse, mutect2, varscan2
